Somatic mutation profile of tumor specimen TCGA-KS-A4I3-01A (aliquot TCGA-KS-A4I3-01A-11D-A257-08) from TCGA case TCGA-KS-A4I3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.0 years (14,992 days).
Specimen TCGA-KS-A4I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 081c203c-d874-47f6-8e88-294a5d7f7afd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4I3-11A (Solid Tissue Normal), aliquot TCGA-KS-A4I3-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81708e02-9d1c-4f18-9791-d966a1f52587

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IGSF9B | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV58069146; called by muse, mutect2, varscan2
- RELN | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.902); catalogued as COSV58991458; called by muse, mutect2, varscan2
- ST18 | c.2976C>A p.S992R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765135070, COSV99388934; called by muse, mutect2, varscan2
- XPOT | c.2279T>G p.F760C | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100225430; called by muse, mutect2, varscan2
- ZMYND11 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs746023648, COSV100556067; called by muse, mutect2, varscan2
- ZNF766 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100765291; called by muse, mutect2, varscan2
- IFT88 | c.1358del p.K453Rfs*5 (on ENST00000319980 / NM_001318493.2; = p.K444Rfs*5 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel, varscan2
- FREM1 | c.367C>T p.L123= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV66528131; called by muse, mutect2, varscan2
- GAS6 | c.912C>G p.T304= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100581293; called by muse, mutect2, varscan2
